Somatic mutation profile of tumor specimen TCGA-DU-5853-01A (aliquot TCGA-DU-5853-01A-11D-1893-08) from TCGA case TCGA-DU-5853, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 29.1 years (10,624 days).
Specimen TCGA-DU-5853-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48ccc619-8948-49a0-b176-84d4382e3a2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-5853-10A (Blood Derived Normal), aliquot TCGA-DU-5853-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bcb22dc-63dd-45b5-8047-09c2ec670e64

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Silent 4, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 44/92 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 34/39 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.6111-1G>A p.X2037_splice | Splice Site (SNP) | VAF 23/30 reads (77%) | catalogued as COSV100971771, COSV64879364; called by muse, mutect2, varscan2
- KMT2C | c.14141A>C p.K4714T | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51461468; called by muse, mutect2, varscan2
- KRT8 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs201875017; called by muse, mutect2, varscan2
- NKX2-2 | c.417G>C p.Q139H | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV65819900; called by muse, mutect2, varscan2
- NOS3 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771783555, COSV52491980, COSV52494026; called by muse, mutect2, varscan2
- PATZ1 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV53230121; called by muse, mutect2, varscan2
- PCDHGB1 | c.991A>G p.I331V | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.251); catalogued as COSV53980440; called by muse, mutect2
- PSG7 | c.244T>C p.Y82H | Missense Mutation (SNP) | VAF 24/501 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV68445670; called by muse, mutect2
- RPTN | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 120/1250 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs760842504, COSV60167149; called by muse, mutect2
- SCN10A | c.1596C>A p.S532R | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as COSV71862059; called by muse, mutect2
- SEMA4F | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 23/277 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.041); catalogued as rs776046741, COSV60284120; called by muse, mutect2
- SERPINA9 | c.1058A>T p.H353L | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54076279; called by muse, mutect2, varscan2
- SLC5A8 | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV73310869; called by muse, mutect2, varscan2
- SLF2 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV53275986; called by muse, mutect2, varscan2
- UNC93A | c.626-2A>G p.X209_splice | Splice Site (SNP) | VAF 32/151 reads (21%) | catalogued as COSV57809425; called by muse, mutect2, varscan2
- ATP5F1B | c.936C>G p.T312= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV56261507, COSV56261675; called by muse, mutect2, varscan2
- GPR31 | c.714C>T p.C238= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as COSV100834151, COSV64761750; called by muse, mutect2
- KMT2A | c.2427T>A p.S809= | Silent (SNP) | VAF 8/184 reads (4%) | catalogued as COSV63288522; called by muse, mutect2
- MUC16 | c.34884A>T p.P11628= | Silent (SNP) | VAF 17/174 reads (10%) | catalogued as COSV67477736; called by muse, mutect2, varscan2
